Somatic mutation profile of tumor specimen HCM-BROD-0014-C71-01A (aliquot HCM-BROD-0014-C71-01A-01D-A77E-36) from HCMI case HCM-BROD-0014-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 68.3 years (24,957 days).
Specimen HCM-BROD-0014-C71-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 627715f5-ff9a-4eb5-9375-c9d5b766140a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0014-C71-10A (Blood Derived Normal), aliquot HCM-BROD-0014-C71-10A-01D-A77E-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/026b12ef-dce5-4efa-a6d0-e0346ceae100

The open-access MAF lists 88 somatic variants for this specimen: 54 protein-altering or splice-affecting, 21 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 50, Silent 21, 3'UTR 5, Intron 4, RNA 2, Frame Shift Del 2, Nonsense Mutation 1, 5'Flank 1, 5'UTR 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS18 | c.3087C>A p.S1029R | Missense Mutation (SNP) | VAF 78/147 reads (53%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.58); catalogued as COSV51408621; called by muse, mutect2, varscan2
- ANKRD24 | c.2719G>A p.E907K | Missense Mutation (SNP) | VAF 98/350 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.107); catalogued as rs866794284, COSV53668949; called by muse, mutect2, varscan2
- C11orf95 | c.1691C>T p.P564L | Missense Mutation (SNP) | VAF 36/103 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.062); catalogued as rs989786394; called by muse, mutect2, varscan2
- C3 | c.595G>A p.V199I | Missense Mutation (SNP) | VAF 196/799 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.61); catalogued as rs147549358, COSV55572426; called by muse, mutect2, varscan2
- CCDC154 | c.1781C>T p.T594M | Missense Mutation (SNP) | VAF 96/192 reads (50%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as rs769618310; called by muse, mutect2, varscan2
- CDH17 | c.2426G>A p.R809H | Missense Mutation (SNP) | VAF 31/130 reads (24%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.459); catalogued as rs201729274, COSV50327363; called by muse, mutect2, varscan2
- CIT | c.5879G>A p.R1960H | Missense Mutation (SNP) | VAF 134/333 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.925); catalogued as rs1174828844, COSV99949344, COSV99950240; called by muse, mutect2, varscan2
- CSAG3 | c.214C>A p.P72T | Missense Mutation (SNP) | VAF 451/1101 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.991); catalogued as rs1365577266; called by muse, mutect2, varscan2
- EGFR | c.368C>A p.S123Y | Missense Mutation (SNP) | VAF 86/357 reads (24%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.766); catalogued as COSV99295901; called by muse, mutect2, varscan2
- FAM205A | c.3833G>A p.R1278H | Missense Mutation (SNP) | VAF 137/390 reads (35%) | SIFT tolerated (0.54); PolyPhen benign (0.085); catalogued as rs1043319691; called by muse, mutect2, varscan2
- HPD | c.914C>T p.T305M | Missense Mutation (SNP) | VAF 82/714 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs200010805; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IRF2 | c.893C>T p.P298L | Missense Mutation (SNP) | VAF 146/259 reads (56%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs761561042, COSV66928939; called by muse, mutect2, varscan2
- ITGA5 | c.3082C>T p.R1028C | Missense Mutation (SNP) | VAF 25/229 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773995957; called by muse, mutect2, varscan2
- KCNJ15 | c.962G>A p.G321E | Missense Mutation (SNP) | VAF 67/165 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1157297131, COSV100154056; called by muse, mutect2, varscan2
- MMP9 | c.956A>G p.N319S | Missense Mutation (SNP) | VAF 148/411 reads (36%) | SIFT tolerated (0.29); PolyPhen benign (0.013); catalogued as rs1284222372; called by muse, mutect2, varscan2
- MSMB | c.22G>A p.V8I | Missense Mutation (SNP) | VAF 45/90 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs370848479; called by muse, mutect2, varscan2
- MYRF | c.2081C>T p.T694M (on ENST00000278836 / NM_001127392.3; = p.T685M on NM_013279.4) | Missense Mutation (SNP) | VAF 90/280 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as rs760054506, COSV53886651; called by muse, mutect2, varscan2
- NME8 | c.485C>T p.P162L | Missense Mutation (SNP) | VAF 27/167 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200863038, COSV52246730, COSV99553828; called by muse, mutect2, varscan2
- NME8 | c.1163T>C p.L388S | Missense Mutation (SNP) | VAF 55/288 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52252047; called by muse, mutect2, varscan2
- OR13C2 | c.242C>T p.T81M | Missense Mutation (SNP) | VAF 67/226 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs370289806; called by muse, mutect2, varscan2
- PHLDB3 | c.1087G>A p.V363M | Missense Mutation (SNP) | VAF 50/185 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.019); catalogued as rs758852591, COSV52667775; called by muse, mutect2, varscan2
- PMS2 | c.1243G>A p.V415M | Missense Mutation (SNP) | VAF 180/606 reads (30%) | SIFT tolerated (0.55); PolyPhen benign (0.022); catalogued as rs138387687; ClinVar: uncertain significance / likely benign; called by mutect2, varscan2
- PTER | c.902C>T p.T301M | Missense Mutation (SNP) | VAF 91/164 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs768587003, COSV54344488; called by muse, mutect2, varscan2
- RBM44 | c.1045G>A p.V349I (on ENST00000611254; = p.V983I on NM_001080504.2) | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.43); PolyPhen benign (0.013); catalogued as rs780466978; called by muse, mutect2, varscan2
- RNF213 | c.12098C>T p.P4033L | Missense Mutation (SNP) | VAF 162/512 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs778482758; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RYR2 | c.13093G>A p.D4365N | Missense Mutation (SNP) | VAF 38/87 reads (44%) | SIFT tolerated (0.2); PolyPhen benign (0.335); catalogued as rs372880584; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SV2C | c.358C>T p.R120W | Missense Mutation (SNP) | VAF 37/78 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.892); catalogued as rs759085527, COSV59227182; called by muse, mutect2, varscan2
- SYT6 | c.1211C>A p.S404Y (on ENST00000610222 / NM_001366225.1; = p.S319Y on NM_205848.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.905); catalogued as COSV101059658; called by muse, mutect2, varscan2
- ZNF618 | c.884C>T p.T295M (on ENST00000374126 / NM_001318042.2; = p.T263M on NM_001318040.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 86/242 reads (36%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.321); catalogued as rs1367764187; called by muse, mutect2, varscan2
- ZNF92 | c.1093G>A p.G365R (on ENST00000328747 / NM_152626.4; = p.G296R on NM_007139.4) | Missense Mutation (SNP) | VAF 57/297 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.801); catalogued as COSV100165919; called by muse, mutect2, varscan2
- AFF2 | c.523A>G p.S175G | Missense Mutation (SNP) | VAF 155/181 reads (86%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- AP2S1 | c.428G>T p.*143Lext*35 | Nonstop Mutation (SNP) | VAF 202/480 reads (42%) | called by muse, mutect2, varscan2
- ATF7 | c.76G>C p.V26L | Missense Mutation (SNP) | VAF 65/222 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- B4GALT7 | c.403G>A p.D135N | Missense Mutation (SNP) | VAF 65/203 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CHIA | c.499G>T p.E167* (on ENST00000343320; = p.E59* on NM_021797.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 9/235 reads (4%) | called by muse, mutect2
- COL11A1 | c.2659C>T p.P887S | Missense Mutation (SNP) | VAF 176/434 reads (41%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DDX53 | c.1786G>C p.D596H | Missense Mutation (SNP) | VAF 45/55 reads (82%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); called by muse, mutect2, varscan2
- DHX16 | c.1187G>A p.R396H | Missense Mutation (SNP) | VAF 114/302 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DIP2B | c.4682G>T p.S1561I | Missense Mutation (SNP) | VAF 123/328 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- EIF4EBP1 | c.158T>C p.I53T | Missense Mutation (SNP) | VAF 84/262 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- EMB | c.124A>T p.T42S | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.433); called by muse, mutect2, varscan2
- EXOC7 | c.360G>C p.Q120H | Missense Mutation (SNP) | VAF 74/211 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- IL4R | c.443C>T p.P148L | Missense Mutation (SNP) | VAF 74/225 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.677); called by muse, mutect2, varscan2
- KANK2 | c.497C>T p.P166L | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- KDM5D | c.760G>T p.D254Y | Missense Mutation (SNP) | VAF 90/116 reads (78%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- LCLAT1 | c.1189G>T p.A397S | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.037); called by muse, varscan2
- MRGPRX4 | c.649A>G p.T217A | Missense Mutation (SNP) | VAF 140/311 reads (45%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- MUC3A | c.558G>T p.M186I | Missense Mutation (SNP) | VAF 111/412 reads (27%) | SIFT tolerated, low confidence (0.08); called by muse, mutect2, varscan2
- PBRM1 | c.206del p.C69Lfs*26 | Frame Shift Del (DEL) | VAF 68/155 reads (44%) | called by mutect2, pindel, varscan2
- PPIE | c.16C>T p.R6C | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- PRKG2 | c.2023A>G p.I675V | Missense Mutation (SNP) | VAF 37/106 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- TJP3 | c.889C>T p.L297F | Missense Mutation (SNP) | VAF 37/196 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.667); called by muse, mutect2, varscan2
- ZBTB21 | c.1329C>G p.I443M | Missense Mutation (SNP) | VAF 109/302 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF708 | c.156del p.I53Sfs*13 | Frame Shift Del (DEL) | VAF 38/200 reads (19%) | called by mutect2, pindel, varscan2
- ABCC2 | c.2781G>A p.L927= | Silent (SNP) | VAF 150/252 reads (60%) | catalogued as rs753596504; called by muse, mutect2, varscan2
- AEBP1 | c.3162C>T p.P1054= | Silent (SNP) | VAF 106/468 reads (23%) | catalogued as rs113676804; called by muse, mutect2, varscan2
- ARHGAP9 | c.177C>T p.S59= | Silent (SNP) | VAF 197/564 reads (35%) | catalogued as rs749278369, COSV62724665; called by muse, mutect2, varscan2
- BCAT2 | c.111G>A p.L37= | Silent (SNP) | VAF 112/276 reads (41%) | called by muse, mutect2, varscan2
- C2CD2 | c.1857C>T p.A619= | Silent (SNP) | VAF 90/286 reads (31%) | called by muse, mutect2, varscan2
- DNAJA2 | c.258T>C p.D86= | Silent (SNP) | VAF 50/128 reads (39%) | called by muse, mutect2, varscan2
- DRC7 | c.2277G>A p.P759= | Silent (SNP) | VAF 42/104 reads (40%) | catalogued as rs201527035, COSV100395742; called by muse, mutect2
- EXOC3L2 | c.1974A>G p.Q658= | Silent (SNP) | VAF 90/410 reads (22%) | called by muse, mutect2, varscan2
- FER1L6 | c.2253A>G p.K751= | Silent (SNP) | VAF 65/191 reads (34%) | called by muse, mutect2, varscan2
- LDB3 | c.1785C>T p.N595= | Silent (SNP) | VAF 100/179 reads (56%) | catalogued as rs757550916; called by muse, mutect2, varscan2
- LOXL2 | c.1779C>T p.Y593= | Silent (SNP) | VAF 32/110 reads (29%) | catalogued as rs1329594914; called by muse, mutect2, varscan2
- LRBA | c.7464C>T p.P2488= | Silent (SNP) | VAF 80/231 reads (35%) | called by muse, mutect2, varscan2
- MAPK9 | c.1176G>A p.S392= | Silent (SNP) | VAF 64/178 reads (36%) | catalogued as rs200820257; called by muse, mutect2, varscan2
- NPTX1 | c.819C>T p.Y273= | Silent (SNP) | VAF 151/430 reads (35%) | catalogued as rs143365668; called by muse, mutect2, varscan2
- OR4D6 | c.609C>T p.N203= | Silent (SNP) | VAF 82/221 reads (37%) | catalogued as rs758028167, COSV55658915; called by muse, mutect2, varscan2
- PCYOX1L | c.702G>A p.G234= | Silent (SNP) | VAF 32/93 reads (34%) | called by muse, mutect2, varscan2
- PMS2 | c.2151G>A p.V717= | Silent (SNP) | VAF 60/333 reads (18%) | called by muse, mutect2, varscan2
- POTED | c.966T>C p.N322= | Silent (SNP) | VAF 9/15 reads (60%) | called by mutect2, varscan2
- SKP2 | c.483T>C p.I161= | Silent (SNP) | VAF 123/304 reads (40%) | called by muse, mutect2, varscan2
- SVOPL | c.732C>T p.R244= (on ENST00000419765; = p.R92= on NM_174959.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 87/406 reads (21%) | catalogued as rs765138699, COSV55993517; called by muse, mutect2, varscan2
- USP38 | c.153G>A p.E51= | Silent (SNP) | VAF 51/173 reads (29%) | catalogued as rs749030582; called by muse, mutect2, varscan2
- APCDD1 | c.-279G>A | 5'UTR (SNP) | VAF 6/14 reads (43%) | called by mutect2, varscan2
- ATG2A | c.*216G>A | 3'UTR (SNP) | VAF 73/189 reads (39%) | called by muse, mutect2, varscan2
- COLEC12 | c.*1C>T | 3'UTR (SNP) | VAF 31/142 reads (22%) | catalogued as rs749935302, COSV68372109; called by muse, mutect2, varscan2
- DNAH10 | c.1816-2668C>T | Intron (SNP) | VAF 22/57 reads (39%) | catalogued as rs75803525; called by muse, mutect2, varscan2
- EFHC1 | c.*3009G>A | 3'UTR (SNP) | VAF 115/314 reads (37%) | called by muse, mutect2, varscan2
- EIF2B4 | c.419-13_419-11del | Intron (DEL) | VAF 75/280 reads (27%) | catalogued as rs779235094; called by pindel, varscan2
- FRMD1 | chr6:168081442 G>A | 5'Flank (SNP) | VAF 73/214 reads (34%) | catalogued as rs780805597; called by muse, mutect2, varscan2
- OPRM1 | c.1165-10679C>A | Intron (SNP) | VAF 17/48 reads (35%) | called by muse, mutect2, varscan2
- OR56B3P | n.623G>T | RNA (SNP) | VAF 12/168 reads (7%) | called by muse, mutect2
- PCDH11Y | c.3129+38T>C | Intron (SNP) | VAF 50/129 reads (39%) | called by muse, mutect2, varscan2
- SLC35E2A | n.1071G>A | RNA (SNP) | VAF 168/649 reads (26%) | called by muse, varscan2
- VNN3 | c.*103G>A | 3'UTR (SNP) | VAF 94/258 reads (36%) | catalogued as rs568114870; called by muse, mutect2, varscan2
- XRCC5 | c.*38G>A | 3'UTR (SNP) | VAF 20/157 reads (13%) | catalogued as rs747121175; called by muse, mutect2, varscan2
